TARGET case TARGET-10-PAPGMV — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/20d0bb67-5ee6-55b5-8f01-cd0fdd1079ee

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 12 years; Vital status: Dead; Days to death: 759 days (2.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 12.5 years (4,559 days); Year of diagnosis: 2006; Days to last follow up: 759 days (2.1 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 28 days; Days to first event: 28 days; First event: Induction Failure.
- Days to follow up: 759 days (2.1 years); Year of follow up: 2008.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- Day 0: Leukocytes 318 ×10³/µL.
- Day 8: Bone Marrow blast count 30%.
- Day 15: Bone Marrow blast count 41%.
- Day 29: Bone Marrow blast count 64%; Minimal Residual Disease (Flow Cytometry) 87.8%.

Biospecimens (3 samples)
- Sample TARGET-10-PAPGMV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPGMV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PAPGMV-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 759
- WBC at Diagnosis: 318.4
- CNS Status at Diagnosis: CNS 1
- MRD Day 29: 87.8
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 30
- BMA Blasts Day 15: 41
- BMA Blasts Day 29: 64
- Down Syndrome: No
- DNA Index: 1.083
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
